Somatic mutation profile of tumor specimen TCGA-MP-A4T8-01A (aliquot TCGA-MP-A4T8-01A-11D-A24P-08) from TCGA case TCGA-MP-A4T8, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.6 years (25,069 days).
Specimen TCGA-MP-A4T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e37f949e-f31e-4c48-abaa-27231b24694b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4T8-10A (Blood Derived Normal), aliquot TCGA-MP-A4T8-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dad599e-bbfb-42a5-b23f-13511e29cf1e

The open-access MAF lists 123 somatic variants for this specimen: 97 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 25, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 2, Splice Site 2, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP2 | c.1671-1G>T p.X557_splice | Splice Site (SNP) | VAF 39/134 reads (29%) | catalogued as rs730880276, CS097855, COSV100668890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.129del p.K44Sfs*7 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs1060499961; ClinVar: pathogenic; called by mutect2, varscan2
- ACSS2 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV99490033; called by muse, mutect2, varscan2
- ACTL7A | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs777158390, COSV100452976; called by muse, mutect2, varscan2
- ADGRB3 | c.3626C>A p.A1209E | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV99484121; called by muse, mutect2, varscan2
- AGPAT1 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as rs753269798, COSV100421684; called by muse, mutect2, varscan2
- AK5 | c.1526A>T p.D509V (on ENST00000354567 / NM_174858.3; = p.D483V on NM_012093.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100643197; called by muse, mutect2, varscan2
- ALDH1A1 | c.926T>C p.I309T | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.258); catalogued as COSV99921543; called by muse, mutect2, varscan2
- ANKRD17 | c.3331C>A p.H1111N | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV100429680; called by muse, mutect2, varscan2
- ANO3 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99884374; called by muse, mutect2, varscan2
- ASTN2 | c.1268G>A p.R423H (on ENST00000313400 / NM_001365069.1; = p.R372H on NM_014010.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as rs149596951; called by muse, mutect2, varscan2
- AXL | c.2470A>G p.M824V (on ENST00000301178 / NM_021913.5; = p.M815V on NM_001699.6) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs760069709, COSV99996968; called by muse, mutect2, varscan2
- BRCA2 | c.5245T>C p.Y1749H | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.079); catalogued as rs876658731, COSV101204513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTAF1 | c.3088G>T p.A1030S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV99795609; called by muse, mutect2, varscan2
- CACNA2D1 | c.311C>A p.A104E | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100666536, COSV100666987; called by muse, mutect2, varscan2
- CALCRL | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101131013; called by muse, mutect2, varscan2
- CDH11 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 37/176 reads (21%) | catalogued as COSV99217974, COSV99219293; called by muse, mutect2, varscan2
- CDK17 | c.476A>G p.E159G | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV99702930; called by muse, mutect2, varscan2
- CLDN25 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101493611; called by muse, mutect2, varscan2
- CNTN2 | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100085303; called by muse, mutect2, varscan2
- CNTNAP5 | c.302A>T p.D101V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101443857; called by muse, mutect2
- CPAMD8 | c.3964G>A p.V1322M (on ENST00000651564; = p.V1275M on NM_015692.5) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781277253, COSV101488549; called by muse, mutect2
- CSMD1 | c.3938C>A p.P1313Q (on ENST00000520002; = p.P1312Q on NM_033225.6) | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59324542; called by muse, mutect2, varscan2
- CSMD2 | c.9188C>T p.P3063L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99592993; called by muse, mutect2, varscan2
- CYP4F8 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100358181, COSV57853963; called by muse, mutect2, varscan2
- DMD | c.1206G>T p.L402F | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV55878721, COSV55878738; called by muse, mutect2, varscan2
- DNAH1 | c.9964A>T p.M3322L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101326571; called by muse, mutect2, varscan2
- DNAH11 | c.11892A>C p.L3964F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100179988; called by muse, mutect2, varscan2
- FAM189A2 | c.1167G>T p.Q389H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99975201; called by muse, mutect2, varscan2
- FAM83D | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs376744439; called by muse, mutect2, varscan2
- FHOD3 | c.3025G>A p.D1009N (on ENST00000359247 / NM_001281739.3; = p.D1026N on NM_025135.5) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs554487359, COSV57165602, COSV99941725; called by muse, mutect2
- GAS6 | c.1997C>A p.T666K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.438); catalogued as COSV100581959; called by muse, mutect2, varscan2
- GIMAP8 | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100217618; called by muse, mutect2, varscan2
- GPC6 | c.1520C>A p.P507H | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.196); catalogued as COSV100989523; called by muse, mutect2, varscan2
- GPRC5A | c.328_329insG p.S110Cfs*42 | Frame Shift Ins (INS) | VAF 75/198 reads (38%) | catalogued as COSV99185593; called by mutect2, pindel, varscan2
- GRM7 | c.2001C>A p.C667* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100737583; called by muse, mutect2, varscan2
- GZF1 | c.1362G>A p.M454I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.125); catalogued as COSV100582615; called by muse, mutect2
- HK3 | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99459004; called by muse, mutect2, varscan2
- HNF4A | c.1150C>A p.H384N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.765); catalogued as COSV100291609, COSV57384566; called by muse, mutect2, varscan2
- HUNK | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99528756; called by muse, mutect2, varscan2
- IGHV1-2 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs781984015; called by muse, mutect2, varscan2
- IGKV1-17 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs530084333; called by muse, mutect2, varscan2
- INTS1 | c.5887A>G p.I1963V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs755240146, COSV101248194; called by muse, mutect2, varscan2
- JAK2 | c.2280A>T p.Q760H | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV101077077; called by muse, mutect2, varscan2
- KCNU1 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV101299358; called by muse, mutect2, varscan2
- LRP1B | c.2333G>A p.R778K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV101258667, COSV67185657; called by muse, mutect2, varscan2
- MPO | c.866C>G p.P289R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV99832879; called by muse, varscan2
- MUC5AC | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); catalogued as rs760860834, COSV100650648, COSV100650724; called by muse, mutect2, varscan2
- MYH1 | c.1366A>T p.R456W | Missense Mutation (SNP) | VAF 94/171 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56850870; called by muse, mutect2, varscan2
- NALCN | c.3347G>T p.G1116V | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216625; called by muse, mutect2, varscan2
- NBN | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99619849; called by muse, mutect2, varscan2
- NCOA1 | c.1911G>T p.L637F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99946683; called by muse, mutect2, varscan2
- NELL2 | c.2099G>T p.C700F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100420277; called by muse, mutect2, varscan2
- NEU4 | c.70G>A p.V24M (on ENST00000391969 / NM_001167602.3; = p.V36M on NM_080741.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771531663, COSV57990073; called by muse, mutect2, varscan2
- NFASC | c.496C>T p.P166S (on ENST00000339876 / NM_001378329.1; = p.P160S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as rs752659990, COSV100364964; called by muse, mutect2, varscan2
- NLGN4X | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52022494, COSV52025091; called by muse, mutect2, varscan2
- NLRP9 | c.761C>A p.P254Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100243268; called by muse, mutect2, varscan2
- NOD2 | c.1926G>T p.R642S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.116); catalogued as COSV100318756; called by muse, mutect2, varscan2
- OR6B3 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); catalogued as rs1431082565, COSV100097494; called by muse, mutect2, varscan2
- OR8K5 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100537266; called by muse, mutect2, varscan2
- PCSK5 | c.3306G>C p.E1102D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV101377618, COSV70446608; called by muse, mutect2, varscan2
- PDILT | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs1030249883, COSV100199674; called by muse, mutect2, varscan2
- PIEZO2 | c.7739C>A p.P2580Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99555277; called by muse, mutect2, varscan2
- PIGQ | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99216322; called by muse, mutect2, varscan2
- PLGRKT | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99803921; called by muse, mutect2, varscan2
- PSMC6 | c.283G>C p.V95L (on ENST00000612399; = p.V81L on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV101471207; called by muse, mutect2, varscan2
- RAPSN | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.137); catalogued as rs749351511, COSV100100321; called by muse, mutect2, varscan2
- RNF166 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.656); catalogued as COSV100455525; called by muse, mutect2, varscan2
- RTN3 | c.1543G>A p.E515K (on ENST00000377819 / NM_001265589.2; = p.E496K on NM_201428.3) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100380281; called by muse, mutect2
- SENP6 | c.1404T>G p.D468E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100519404; called by muse, mutect2, varscan2
- SLC29A4 | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.905); catalogued as COSV51876092, COSV99786875; called by muse, varscan2
- SMARCD2 | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV99856554; called by muse, mutect2, varscan2
- SORCS3 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.728); catalogued as rs138506167, COSV63829105; called by muse, mutect2, varscan2
- SPEG | c.9331A>C p.N3111H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100405164; called by muse, mutect2
- STX4 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV100572963; called by muse, mutect2, varscan2
- TBC1D14 | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV101298993; called by muse, mutect2, varscan2
- TBC1D14 | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as COSV101298994; called by muse, mutect2, varscan2
- THBD | c.1274G>A p.C425Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65702182; called by muse, mutect2, varscan2
- TRANK1 | c.5532G>T p.K1844N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV100083942; called by muse, mutect2
- TRBV4-2 | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.461); catalogued as rs1275198461; called by muse, mutect2
- TRO | c.510G>T p.L170F | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV99436965; called by muse, mutect2, varscan2
- TRO | c.1377C>A p.D459E | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99436967; called by muse, mutect2, varscan2
- UACA | c.2771G>T p.S924I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100537626; called by muse, mutect2, varscan2
- UBE3A | c.1039A>C p.I347L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); catalogued as COSV99217603; called by muse, mutect2, varscan2
- VPS35 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as rs758068523, COSV100140727; called by muse, mutect2, varscan2
- VPS4A | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.909); catalogued as COSV99652061; called by muse, mutect2, varscan2
- XKR7 | c.1015A>T p.M339L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101629282; called by muse, mutect2, varscan2
- ZNF486 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100631368, COSV58718350; called by muse, mutect2, varscan2
- ZNF714 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.303); catalogued as COSV52510963, COSV99395439; called by muse, mutect2, varscan2
- AKR7A2 | c.693_694insGT p.L232Vfs*3 | Frame Shift Ins (INS) | VAF 26/82 reads (32%) | called by mutect2, pindel*, varscan2
- FASTKD1 | c.1189del p.A397Rfs*11 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- HYKK | c.656_660del p.R219Lfs*8 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- PCDHGA12 | c.2785_*3del | Nonstop Mutation (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel
- SLC22A3 | c.1398-1_1398del p.X466_splice | Splice Site (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- TIGD4 | c.622_623del p.K208Vfs*45 | Frame Shift Del (DEL) | VAF 42/114 reads (37%) | called by mutect2, pindel, varscan2
- TRAV27 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRE2 | c.2223G>T p.L741= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV100216298; called by muse, mutect2, varscan2
- C3AR1 | c.219C>A p.L73= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99368808; called by muse, mutect2, varscan2
- C6 | c.2442C>A p.P814= | Silent (SNP) | VAF 46/226 reads (20%) | catalogued as COSV54711019, COSV99667504; called by muse, mutect2, varscan2
- CASQ2 | c.201A>G p.Q67= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV99798025; called by muse, mutect2, varscan2
- CFHR5 | c.129C>T p.S43= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs1308588971, COSV56826107; called by muse, mutect2, varscan2
- CSAG3 | c.339A>G p.E113= | Silent (SNP) | VAF 44/76 reads (58%) | called by muse, mutect2, varscan2
- FAM135B | c.2952T>A p.T984= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV99425921; called by muse, mutect2, varscan2
- HDAC9 | c.1017C>A p.S339= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101286885; called by muse, mutect2, varscan2
- KCNB2 | c.1293G>A p.E431= | Silent (SNP) | VAF 89/325 reads (27%) | catalogued as rs752583937, COSV101578885; called by mutect2, varscan2
- KLHL3 | c.285C>T p.D95= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs779945979, COSV100553422; called by muse, mutect2, varscan2
- LRIF1 | c.303C>T p.A101= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV100870889; called by muse, mutect2, varscan2
- MEOX2 | c.814C>T p.L272= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as COSV100012364; called by muse, mutect2, varscan2
- MICAL3 | c.2673C>A p.I891= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV52902442, COSV99259711; called by muse, mutect2, varscan2
- NEUROG2 | c.292C>A p.R98= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100511896; called by muse, mutect2
- NMT1 | c.987G>A p.L329= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV99364910; called by muse, mutect2, varscan2
- OTUD6B | c.222T>C p.T74= | Silent (SNP) | VAF 116/184 reads (63%) | catalogued as COSV99576033; called by muse, mutect2, varscan2
- PCDHGA3 | c.1548G>T p.A516= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV99542934; called by muse, mutect2, varscan2
- PDGFRL | c.1083T>C p.N361= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs964422008, COSV99286571; called by muse, mutect2, varscan2
- RBM27 | c.699A>G p.A233= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs536610636, COSV99506435; called by muse, mutect2, varscan2
- RSPH10B2 | c.2487G>T p.V829= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99786276; called by mutect2, varscan2
- SLC12A3 | c.1047C>A p.P349= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV99344065, COSV99344115, COSV99344547; called by muse, mutect2, varscan2
- SRCAP | c.4779A>C p.P1593= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- TEX15 | c.4401G>A p.A1467= (on ENST00000256246; = p.A1850= on NM_001350162.2) | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs746702451, COSV99821825, COSV99822248; called by muse, mutect2, varscan2
- UTP20 | c.8166G>A p.E2722= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99882143; called by muse, mutect2
- ZNF491 | c.855A>T p.S285= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100022001; called by muse, mutect2, varscan2
- POLA1 | c.2947-21325dup | Intron (INS) | VAF 69/123 reads (56%) | called by mutect2, pindel, varscan2
